Somatic mutation profile of tumor specimen TCGA-A2-A04W-01A (aliquot TCGA-A2-A04W-01A-31D-A10Y-09) from TCGA case TCGA-A2-A04W, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Apocrine adenocarcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 50.2 years (18,345 days).
Specimen TCGA-A2-A04W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31e707ed-a30b-42b3-a1ee-a1ee2f8b46ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A04W-10A (Blood Derived Normal), aliquot TCGA-A2-A04W-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a798d02-d047-4789-af8a-292e974d4a5b

The open-access MAF lists 149 somatic variants for this specimen: 112 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 33, Nonsense Mutation 14, Splice Site 3, 3'Flank 2, Splice Region 1, Intron 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNPTAB | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 30/225 reads (13%) | catalogued as rs281864982, CM100341, COSV54779098, COSV68449787; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 32/92 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABL2 | c.679G>T p.D227Y (on ENST00000502732 / NM_007314.4; = p.D212Y on NM_005158.5) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61015012; called by muse, mutect2, varscan2
- ADGRB3 | c.3768G>C p.L1256F | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.033); catalogued as COSV104381150, COSV53246894; called by muse, mutect2, varscan2
- ARMC4 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV53465549; called by muse, mutect2, varscan2
- ASNSD1 | c.1792C>G p.L598V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.017); catalogued as COSV53623837; called by muse, mutect2
- ATP10B | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV58779065; called by muse, mutect2, varscan2
- ATR | c.7724C>T p.A2575V | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as rs762196224, COSV63387071; called by muse, mutect2, varscan2
- ATXN2 | c.798G>A p.M266I (on ENST00000550104; = p.M106I on NM_002973.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV66483497; called by muse, varscan2
- C21orf91 | c.58G>T p.V20F | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV53033008; called by muse, mutect2, varscan2
- CAD | c.2277G>A p.M759I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV53027533; called by muse, mutect2, varscan2
- CATSPERE | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.074); catalogued as COSV100834975; called by muse, mutect2
- CDH15 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs374936482; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100575217; called by muse, mutect2
- CFAP74 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.149); catalogued as COSV54568595, COSV54572173; called by muse, mutect2, varscan2
- CHD4 | c.4900G>T p.E1634* (on ENST00000357008 / NM_001363606.2; = p.E1645* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 17/139 reads (12%) | catalogued as COSV58902285; called by muse, mutect2, varscan2
- CPSF2 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as COSV100102659; called by muse, mutect2
- CR1 | c.5761G>A p.E1921K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as COSV65458695; called by muse, mutect2
- CRYGC | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV52205438; called by muse, mutect2, varscan2
- CSN2 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 18/325 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs1388507323, COSV100778751; called by muse, mutect2
- CTDSP1 | c.687G>C p.M229I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV99811891; called by muse, mutect2, varscan2
- DCAF5 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV100432305; called by muse, mutect2
- DEFB128 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as COSV57685385, COSV57685654; called by muse, mutect2, varscan2
- DNAJA2 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 9/117 reads (8%) | catalogued as COSV100398817; called by muse, mutect2
- DNAJC25-GNG10 | c.378G>C p.Q126H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV65349830; called by muse, mutect2, varscan2
- DOCK7 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99223452; called by muse, mutect2, varscan2
- DYSF | c.4411-1G>A p.X1471_splice | Splice Site (SNP) | VAF 15/98 reads (15%) | catalogued as COSV50399356; called by muse, mutect2
- EFCAB5 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV100299896; called by muse, mutect2
- EGR2 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54347108; called by muse, mutect2, varscan2
- EPB41 | c.1070C>G p.P357R (on ENST00000343067 / NM_001166005.2; = p.P148R on NM_004437.4) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202197419; called by muse, mutect2, varscan2
- FAM171A1 | c.768G>C p.K256N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100968131; called by muse, mutect2
- FAP | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV99501878; called by muse, mutect2
- FAT4 | c.14447C>G p.S4816C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100628212, COSV58688569; called by muse, mutect2, varscan2
- GRID2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV56212737; called by muse, mutect2, varscan2
- GRIFIN | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as COSV101321744; called by muse, mutect2
- GUCY2C | c.1505G>A p.R502K | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as COSV99663363; called by muse, mutect2
- H2AC15 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV57585783; called by muse, mutect2, varscan2
- HTR1D | c.1053C>G p.I351M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100024728; called by muse, mutect2
- HTT | c.7393G>A p.E2465K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61863083; called by muse, mutect2, varscan2
- IGLON5 | c.944C>G p.S315* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV54536185; called by muse, mutect2, varscan2
- IL13RA2 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV99682940; called by muse, mutect2
- IL1RAPL1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100145870, COSV56258589; called by muse, mutect2
- IL1RAPL1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); catalogued as rs766627012, COSV56266242; called by muse, mutect2, varscan2
- ISX | c.382-1G>C p.X128_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as COSV58086033, COSV58086313; called by muse, mutect2, varscan2
- KCTD1 | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58687057; called by muse, mutect2, varscan2
- KNL1 | c.2334G>A p.M778I (on ENST00000346991 / NM_170589.5; = p.M752I on NM_144508.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV61155462; called by muse, mutect2, varscan2
- MAP2 | c.5158G>A p.G1720S | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210962424, COSV99558531, COSV99559139; called by muse, mutect2
- MAPK8 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.494); catalogued as COSV100827390; called by muse, mutect2
- MDN1 | c.14490G>C p.K4830N | Missense Mutation (SNP) | VAF 45/386 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV65522685; called by muse, mutect2, varscan2
- MMS19 | c.1925C>A p.S642* | Nonsense Mutation (SNP) | VAF 19/130 reads (15%) | catalogued as COSV59135402; called by muse, mutect2, varscan2
- MUC17 | c.10795C>T p.P3599S | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.594); catalogued as COSV60290482; called by muse, mutect2, varscan2
- MYBPC1 | c.1013G>C p.R338T (on ENST00000550270 / NM_206820.2; = p.R363T on NM_002465.4) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV62253553; called by muse, mutect2, varscan2
- NCAPG2 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51988285; called by muse, mutect2, varscan2
- NEXMIF | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV50036050; called by muse, mutect2, varscan2
- NFE2L3 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99283558; called by muse, mutect2
- NLRP13 | c.1340C>G p.S447* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | catalogued as COSV61622139; called by muse, mutect2, varscan2
- NLRP13 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.176); catalogued as COSV61622143; called by muse, mutect2, varscan2
- NPAT | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53718369; called by muse, mutect2
- NPTN | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99766340; called by muse, mutect2, varscan2
- NUFIP1 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64791278; called by muse, mutect2, varscan2
- NUFIP2 | c.2003-1G>A p.X668_splice | Splice Site (SNP) | VAF 9/136 reads (7%) | catalogued as COSV99837277; called by muse, mutect2
- NUTM1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as rs1324981326, COSV60995468; called by muse, mutect2, varscan2
- OPRL1 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100401978, COSV61091837, COSV61092669; called by muse, mutect2, varscan2
- OR52N5 | c.603C>G p.I201M | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57698966; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1062G>C p.L354F | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV101250346, COSV68210531; called by muse, mutect2
- PCDHA7 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV65344570; called by muse, mutect2, varscan2
- PCDHB7 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50773732; called by muse, varscan2
- PCDHGB7 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53960679; called by muse, mutect2, varscan2
- PKHD1 | c.8149G>T p.E2717* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as COSV100581757; called by muse, mutect2, varscan2
- PLEC | c.4341G>C p.E1447D (on ENST00000322810 / NM_201380.4; = p.E1337D on NM_000445.5) | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100512089, COSV59643347; called by muse, mutect2, varscan2
- PLPPR5 | c.952G>A p.A318T (on ENST00000263177 / NM_001037317.2; = p.A313T on NM_001010861.3) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs369611724; called by muse, mutect2, varscan2
- PLXDC1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.536); catalogued as COSV100195130, COSV59551494; called by muse, mutect2, varscan2
- POC5 | c.432A>G p.I144M (on ENST00000428202 / NM_001099271.2; = p.I119M on NM_152408.2) | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as rs1257130117, COSV100994300; called by muse, mutect2
- PTH2R | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55916544; called by muse, mutect2, varscan2
- RAB6C | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV101308474; called by muse, mutect2
- RBM48 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99720092; called by muse, mutect2, varscan2
- RGS22 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV62662475; called by muse, mutect2, varscan2
- RYR2 | c.11050G>A p.E3684K | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV63688714; called by muse, mutect2, varscan2
- SCN9A | c.2665G>T p.G889C (on ENST00000303354; = p.G878C on NM_002977.3) | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100311868; called by muse, mutect2
- SEMA3A | c.1288C>G p.Q430E | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.24); catalogued as COSV54870954, COSV54873880; called by muse, mutect2, varscan2
- SEMA3C | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 20/166 reads (12%) | catalogued as COSV54847780; called by muse, mutect2, varscan2
- SLC34A3 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as CM087505, COSV63187197; called by mutect2, varscan2
- SLC9A5 | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV100237162; called by muse, mutect2, varscan2
- SOD1 | c.315C>G p.I105M | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV54256282; called by muse, mutect2, varscan2
- SPEM2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs560059533, COSV100080869; called by muse, mutect2, varscan2
- SPINK2 | c.151G>C p.V51L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV50534068; called by muse, mutect2, varscan2
- STON1 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV59131534; called by muse, mutect2, varscan2
- TAF1L | c.692T>C p.L231S | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV54262853; called by muse, mutect2, varscan2
- TAS2R9 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.34); catalogued as COSV53689057; called by muse, mutect2, varscan2
- TBCD | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs1355596010, COSV62801985; called by muse, mutect2, varscan2
- TG | c.4882G>T p.D1628Y | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55078840; called by muse, mutect2, varscan2
- TLN1 | c.924C>A p.Y308* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV59208029; called by muse, mutect2, varscan2
- TLN1 | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59208037; called by muse, mutect2, varscan2
- TLR3 | c.1567G>C p.D523H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as COSV99710873, COSV99711337; called by muse, mutect2
- TMPRSS11E | c.284C>A p.P95Q | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV59519442; called by muse, mutect2, varscan2
- TRIM42 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1250313209, COSV53883465; called by muse, mutect2, varscan2
- ULBP3 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV66254266; called by muse, mutect2, varscan2
- UNC5C | c.2101G>A p.V701I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV71660102; called by muse, mutect2, varscan2
- USH2A | c.5653A>G p.R1885G | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs768501386, CM080603, COSV56378290; called by muse, mutect2, varscan2
- USP9X | c.3418G>C p.D1140H | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100198664; called by muse, mutect2
- VEPH1 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs373769969; called by muse, mutect2, varscan2
- VSTM4 | c.459C>G p.V153= | Splice Region (SNP) | VAF 27/88 reads (31%) | catalogued as COSV60526884; called by muse, mutect2, varscan2
- WWC1 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54649262; called by muse, mutect2, varscan2
- YES1 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs763332220, COSV58850511; called by muse, mutect2, varscan2
- ZIC3 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV54974366; called by muse, mutect2, varscan2
- ZMYM3 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100077593; called by muse, mutect2
- ZNF296 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs139536353, COSV55519850; called by muse, mutect2, varscan2
- ZNF667 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 26/215 reads (12%) | catalogued as COSV52635097; called by muse, mutect2, varscan2
- ZNF772 | c.1443G>T p.W481C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV58410957; called by muse, mutect2, varscan2
- ZNF808 | c.1216A>G p.K406E | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV63120093; called by muse, mutect2, varscan2
- TMC5 | c.2619_2620del p.F874Hfs*64 (on ENST00000396229 / NM_001105248.1; = p.F628Hfs*64 on NM_024780.5) | Frame Shift Del (DEL) | VAF 20/174 reads (11%) | called by pindel, varscan2
- CNGA3 | c.1554G>A p.E518= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs544874644, COSV55624797; called by muse, mutect2, varscan2
- DDX49 | c.993C>T p.I331= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV55356400; called by muse, mutect2, varscan2
- DLG1 | c.2187T>C p.D729= (on ENST00000419354 / NM_001290983.1; = p.D751= on NM_004087.2) | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as COSV100014871; called by muse, mutect2
- DNAH5 | c.13233C>T p.L4411= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV54229271; called by muse, mutect2, varscan2
- EDC4 | c.1440C>A p.A480= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV62766221; called by muse, mutect2, varscan2
- FAM47A | c.168C>T p.D56= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs200832901, COSV60497226; called by muse, mutect2, varscan2
- FREM1 | c.27G>A p.A9= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs760254031, COSV66518670; called by muse, mutect2, varscan2
- GABRQ | c.456C>T p.F152= | Silent (SNP) | VAF 24/197 reads (12%) | catalogued as rs781952537, COSV64782288; called by muse, mutect2, varscan2
- GINS4 | c.369G>A p.S123= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs778923827, COSV52530862; called by muse, mutect2, varscan2
- GTPBP4 | c.813C>G p.L271= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as rs376563095; called by muse, mutect2, varscan2
- ITGAE | c.2895C>T p.F965= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs747320321, COSV54000547; called by muse, mutect2
- KIF1C | c.669C>T p.I223= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs375834968; called by muse, mutect2, varscan2
- LMO7 | c.4938C>T p.I1646= (on ENST00000357063; = p.I1327= on NM_005358.5) | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV58538223; called by muse, mutect2, varscan2
- LRRC29 | c.495C>G p.L165= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100440695; called by muse, mutect2
- MBP | c.282C>T p.L94= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV100592503; called by muse, mutect2, varscan2
- MUC16 | c.16527T>G p.S5509= | Silent (SNP) | VAF 19/209 reads (9%) | catalogued as COSV67446521, COSV67464155; called by muse, mutect2
- MUC4 | c.14055C>T p.F4685= (on ENST00000463781 / NM_018406.7; = p.F449= on NM_004532.6) | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs540712980, COSV57770161; called by muse, mutect2, varscan2
- NBAS | c.6057G>A p.Q2019= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs773935072, COSV55718145; called by muse, mutect2, varscan2
- POU6F2 | c.1641G>C p.L547= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV68874292; called by muse, mutect2, varscan2
- SBNO1 | c.3237G>C p.L1079= (on ENST00000420886; = p.L1078= on NM_018183.5) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV57342216; called by muse, mutect2, varscan2
- SEMA3E | c.243C>T p.L81= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV57092720; called by muse, mutect2, varscan2
- SMO | c.1665G>A p.Q555= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV50830308; called by muse, mutect2, varscan2
- SRBD1 | c.1347G>A p.T449= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV55399452; called by muse, mutect2, varscan2
- TBC1D31 | c.1542C>T p.I514= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV54866844; called by muse, mutect2, varscan2
- THBS3 | c.2292C>G p.G764= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as COSV58616001; called by muse, mutect2, varscan2
- TNRC18 | c.4665G>A p.L1555= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV68165959; called by muse, mutect2, varscan2
- TTC39C | c.1710C>T p.I570= (on ENST00000317571 / NM_001135993.2; = p.I509= on NM_153211.4) | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV58217791; called by muse, mutect2, varscan2
- TTLL11 | c.1182C>G p.L394= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100388540; called by muse, mutect2, varscan2
- TTLL5 | c.2140C>T p.L714= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100089444; called by muse, mutect2
- UBAC1 | c.264C>G p.V88= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV65614168; called by muse, mutect2, varscan2
- UBN2 | c.843G>A p.R281= | Silent (SNP) | VAF 26/205 reads (13%) | catalogued as rs760915939, COSV56030908, COSV56031170; called by muse, mutect2, varscan2
- USH2A | c.882C>T p.L294= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV56378308; called by muse, mutect2, varscan2
- ZFYVE26 | c.1455C>A p.V485= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100720172; called by muse, mutect2
- AL133467.5 | chr14:95663484 C>G | 3'Flank (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446957 G>A | 3'Flank (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- MIR369 | n.37G>A | RNA (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- NACA | c.70+3185G>C | Intron (SNP) | VAF 27/159 reads (17%) | catalogued as COSV63270301; called by muse, mutect2, varscan2
